Somatic mutation profile of tumor specimen 0DO7MF from CCDI case PBCCGC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 0.6 years (212 days).
Specimen 0DO7MF: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75ce0cb3-fe8c-450b-a4bd-1e0992311814.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO7LY (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a48bb76a-2b47-4121-8236-db7dab91c75f

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 5'UTR 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FMO3 | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 62/658 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.808); catalogued as rs72549331, CM992887; ClinVar: likely pathogenic; called by muse, mutect2
- PIK3CG | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 48/397 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs757016725, COSV63247823; called by muse, mutect2, varscan2
- ARC | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 51/516 reads (10%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.01); called by muse, mutect2
- NCAM1 | c.1971A>C p.K657N (on ENST00000316851 / NM_181351.5; = p.K647N on NM_000615.7) | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- BPIFB2 | c.318G>A p.E106= | Silent (SNP) | VAF 68/283 reads (24%) | catalogued as rs1466656728, COSV50071400; called by muse, mutect2, varscan2
- DDX3X | c.1022+42T>C | Intron (SNP) | VAF 41/340 reads (12%) | called by muse, mutect2, varscan2
- GLRA3 | c.-9C>A | 5'UTR (SNP) | VAF 41/319 reads (13%) | called by muse, mutect2, varscan2
